CCDI case PBBUBZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f626cada-3594-4719-ae74-b8a8f2978d31

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.9 years (1,413 days).

Biospecimens (3 samples)
- Sample 0DH27G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH28R: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH292: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
